Gene-level copy-number profile of tumor specimen MP2PRT-PAUIAH-TMP1-A from MP2PRT case MP2PRT-PAUIAH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.3 years (2,652 days).
Specimen MP2PRT-PAUIAH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f10a5ac0-dfb2-4170-9895-76436eab7328.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUIAH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/5f511a28-a7e4-4f37-b231-8d1dad2c4b90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1,451; copy number 2: 53,881; copy number 3: 3,541.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,836,436–8,226,614, 25 genes: DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr14:106,564,375–106,566,555, 2 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
